Gene-level copy-number profile of tumor specimen TCGA-56-5898-01A from TCGA case TCGA-56-5898, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 69.7 years (25,441 days).
Specimen TCGA-56-5898-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.816e9dcd-6b49-409a-8803-fbac463bd4f5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-56-5898-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e7ef5c94-b5fb-4048-9ae3-cb6cb6752d84

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2; copy number 2: 19,697; copy number 3: 11,255; copy number 4: 22,307; copy number 5: 4,250; copy number 6: 1,178; copy number 7: 889; copy number 8: 53; copy number 9: 2; copy number 10: 18; copy number 11: 8; copy number 12: 21; copy number 13: 14; copy number 17: 1; copy number 18: 11; copy number 20: 3; copy number 24: 8; copy number 26: 3; copy number 27: 3; copy number 28: 3; copy number 30: 5; copy number 31: 3; copy number 38: 5; copy number 57: 31; copy number 64: 16; copy number 66: 3; copy number 71: 1; copy number 74: 11; copy number 75: 3; copy number 81: 2; copy number 83: 7; copy number 87: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-56-5898-01A-11D-1631-01): tumor purity 0.36, ploidy 3.33, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 186 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:177,294,442–177,767,379, 4 genes, copy number 9–26 (within-gene range 8–26): LINC00501, ASS1P7, AC117465.1, LINC00578.
- chr3:177,621,382–178,937,352, 16 genes, copy number 9–87 (within-gene range 4–87): AC026355.3, AC026355.1, AC026355.2, AC026355.4, LINC02015, AC007953.1, AC007953.2, RNU6-1120P, AC110992.1, AC117453.1, KCNMB2, AC117457.1, LINC01014, RNA5SP148, PPIAP75, KCNMB2-AS1.
- chr3:180,542,701–180,542,836, 1 gene, copy number 71: U8.
- chr3:180,989,762–181,836,880, 1 gene, copy number 38 (within-gene range 7–83): SOX2-OT.
- chr3:181,372,732–182,158,313, 16 genes, copy number 30–83: AC068308.1, RPL7AP25, AC125613.1, AC125613.2, AC117415.1, SOX2, AC117415.2, RN7SL703P, RNA5SP150, AC007547.2, AC007547.1, LINC01206, RN7SKP265, AC012081.2, AC012081.1, AC109131.1.
- chr3:182,739,669–183,163,839, 10 genes, copy number 74: AC083801.2, AC069431.1, ATP11B, AC069431.2, AC092953.2, DCUN1D1, AC092953.1, MCCC1, MCCC1-AS1, LAMP3.
- chr3:183,258,300–183,258,416, 1 gene, copy number 74: RNA5SP151.
- chr3:183,806,457–184,293,031, 31 genes, copy number 57 (within-gene range 7–57): YEATS2-AS1, AC131160.1, MAP6D1, PARL, RPSAP31, MIR4448, CYP2AB1P, ABCC5, ABCC5-AS1, EEF1A1P8, HTR3D, HTR3C, HTR3C2P, Y_RNA, HTR3E-AS1, HTR3E, HSP90AA5P, AC131235.3, AC131235.2, EIF2B5, AC131235.1, DVL3, AP2M1, ABCF3, VWA5B2, MIR1224, ALG3, EEF1AKMT4, EEF1AKMT4-ECE2, CAMK2N2, ECE2.
- chr8:120,059,780–122,127,184, 15 genes, copy number 10 (within-gene range 7–10): COL14A1, MRPL13, MTBP, SNTB1, NCAPGP1, AC104958.1, AC104958.2, AC068413.1, AC011626.1, RPL35AP19, HAS2, HAS2-AS1, LINC02855, AC037486.1, MRPS36P3.
- chr8:126,556,323–127,419,050, 1 gene, copy number 31 (within-gene range 8–81): PCAT1.
- chr8:126,671,522–128,564,679, 28 genes, copy number 17–81: RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824.
- chr8:130,780,301–131,432,869, 6 genes, copy number 11: ADCY8, AC103726.1, AC103726.2, AC087341.1, AC104257.1, SNORA72.
- chr12:66,347,431–68,793,964, 44 genes, copy number 10–24 (within-gene range 2–24): GRIP1, OSBPL9P5, OSBPL9P4, AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, AC078983.1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3.
- chr12:69,348,381–69,460,724, 6 genes, copy number 18: LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373.
- chr12:70,366,290–70,637,440, 5 genes, copy number 13: KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1.
- chr12:70,671,918–70,672,856, 1 gene, copy number 13: FAHD2P1.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
